Gene-level copy-number profile of tumor specimen TCGA-CS-6666-01A from TCGA case TCGA-CS-6666, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 22.8 years (8,340 days).
Specimen TCGA-CS-6666-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.5ef6b48c-a936-4a3b-9d25-5e3f768da7c5.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CS-6666-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4028e064-6f24-49bc-84d1-ae709a11aa8d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4,054; copy number 1: 8,318; copy number 2: 40,278; copy number 3: 4,350; copy number 4: 2,075; copy number 5: 41; copy number 7: 635; copy number 8: 521.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CS-6666-01A-11D-1892-01): tumor purity 0.25, ploidy 4.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1,148 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:231,645,998–242,160,153, 261 genes (broad region; genes not listed).
- chr4:114,827,763–118,640,858, 41 genes (within-gene range 0–1): NDST4, MRPS33P3, RPF2P2, PGAM4P2, KRT18P21, AC027613.1, EIF3KP3, TTC39CP1, MTRNR2L13, MIR1973, TRMT112P1, CUL4AP1, AC106892.1, ACTN4P1, AC093765.5, AC093765.4, AC093765.3, AC093765.2, RNU6-119P, AC093765.1, TRAM1L1, AC107399.1, LINC02262, LINC02263, LINC01378, RPSAP35, NT5C3AP1, AC092661.1, LINC02264, NDST3, FKBP4P1, SNHG8, SNORA24, PRSS12, NDUFS5P5, AC092670.1, CEP170P1, AC110079.1, RNU6-1054P, CICP16, SEPTIN14P4.
- chr4:127,028,107–134,327,977, 71 genes (within-gene range 0–1) (broad region; genes not listed).
- chr4:145,599,042–146,200,000, 12 genes (within-gene range 0–1): MMAA, NCOA4P3, AC093864.1, C4orf51, ZNF827, AC104791.2, AC104791.1, Y_RNA, AC108206.1, LINC01095, LSM6, AC097372.2.
- chr4:148,445,703–154,612,967, 104 genes (within-gene range 0–1) (broad region; genes not listed).
- chr4:166,733,384–169,612,627, 28 genes (within-gene range 0–3): SPOCK3, RNA5SP171, AC079349.1, RN7SL776P, PHBP14, RN7SKP188, AC105148.1, AC116634.1, ANXA10, AC068989.1, DDX60, DDX60L, AC079926.1, PALLD, BTF3L4P4, PALLD-AS1, RNU6-1336P, RPL9P16, AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1, NEK1.
- chr4:180,573,464–183,419,805, 34 genes: NDUFB5P1, AC104803.1, LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2, AC084741.1, TEMN3-AS1, RN7SKP13, TENM3-AS1, CCNHP1, TENM3, AC108142.1, MIR1305, RNU2-34P, RN7SKP67, AC079226.2, AC079226.1, AC114798.1, AC079766.1, DCTD, AC019193.4, AC019193.1, CIBAR1P2, AC019193.3, AC019193.2, WWC2-AS2, WWC2, WWC2-AS1, CLDN22, CLDN24, AC093844.1, AC112698.1.
- chr4:187,198,218–190,092,279, 60 genes: AC108046.1, LINC02374, AC097652.1, LINC02514, LINC02515, AC093763.2, AC093763.1, LINC02492, AC097521.1, ADAM20P3, AC108073.3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr8:39,314,591–39,580,134, 3 genes (within-gene range 0–3): ADAM5, ADAM3A, AC123767.1.
- chr11:167,784–1,697,755, 98 genes (broad region; genes not listed).
- chr19:53,365,693–58,605,223, 436 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,197 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:68,330,955–68,819,023, 1 gene, copy number 5 (within-gene range 3–5): C8orf34.
- chr8:68,695,643–145,066,685, 1,196 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,283. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
